Surgical pathology report (de-identified scan), TCGA case TCGA-SX-A7SR, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-SX-A7SR-01A (Primary Tumor).

[page 1 of 3]
Result Type: Surgical Pathology Report
Result Date:
Performed By:
Encounter info:

ICD-O-3
Carcinoma, papillary renal cell
8260/3
Site R Kidney NOS
C64.9
JW 10/5/13

Surgical Pathology Report

Final

Surgical Pathology Report

REVISED REPORT

Clinic Number: Name:

DIAGNOSIS:

AMENDED REPORT :

The tumor grade was incorrectly given in the synoptic portion of the final diagnosis. The correct Fuhrman nuclear grade is grade 3, as stated in the summary paragraph for part B, at the beginning of the final diagnosis section.

AMENDED FINAL DIAGNOSIS:

A. Lower pole cyst, right kidney, excision: Benign fibrous-walled cyst lined by flattened tubular epithelium, with associated smooth muscle and renal cortical elements present, consistent with simple renal cyst. Additional findings include the presence of multiple (at least 3) tubulopapillary adenomas, each measuring less than 2 mm. No evidence of malignancy detected.

B. Mass, upper pole, right kidney, right partial nephrectomy: Papillary renal cell carcinoma, Fuhrman nuclear grade 3, forming a partly cystic and necrotic mass that measures approximately 10 cm in diameter. There is extensive necrosis and hemorrhage, with numerous foamy macrophages present. The morphologic/histologic pattern is predominantly type 2, although a minor component of type 1 is identified. The renal parenchymal margin of resection is negative for tumor. See synoptic report, below:

Procedure/laterality: Partial nephrectomy, right.

Histologic type: Papillary renal cell carcinoma.

Nuclear grade (Fuhrman, 1-4): 3.

Tumor size: 10 cm.

Tumor site: Upper pole, right kidney.

Tumor focality: N/A.

Sarcomatoid features: Not identified.

Tumor necrosis: Present.

Macroscopic extent of tumor: Tumor limited to kidney.

Microscopic tumor extension: Tumor limited to kidney.

Surgical margins: Negative.

Lymph-vascular invasion: Not identified.

Lymph nodes: N/A.

Pathologic findings in nonneoplastic kidney: N/A.

Pathologic staging (AJCC 2010): pT2a.

Biorepository sample: Mirror image section of tissue sent for biobanking is positive for involvement by papillary renal cell

[page 2 of 3]
carcinoma (95%). A separate smaller piece of nonneoplastic kidney is negative for involvement by tumor.
Block(s) containing malignancy suitable for additional testing:
Blocks B3, B4, B8, and B9.

AMENDMENTS: (Previous Signout Date:
Revision Description:
See final report for amendment reason.
Original Diagnosis....

A. Lower pole cyst, right kidney, excision: Benign fibrous-walled cyst lined by flattened tubular epithelium, with associated smooth muscle and renal cortical elements present, consistent with simple renal cyst. Additional findings include the presence of multiple (at least 3) tubulopapillary adenomas, each measuring less than 2 mm. No evidence of malignancy detected.

B. Mass, upper pole, right kidney, right partial nephrectomy: Papillary renal cell carcinoma, Fuhrman nuclear grade 3, forming a partly cystic and necrotic mass that measures approximately 10 cm in diameter. There is extensive necrosis and hemorrhage, with numerous foamy macrophages present. The morphologic/histologic pattern is predominantly type 2, although a minor component of type 1 is identified. The renal parenchymal margin of resection is negative for tumor. See synoptic report, below:

Procedure/laterality: Partial nephrectomy, right.
Histologic type: Papillary renal cell carcinoma.
Nuclear grade (Fuhrman, 1-4): 4.
Tumor size: 10 cm.
Tumor site: Upper pole, right kidney.
Tumor focality: N/A.
Sarcomatoid features: Not identified.
Tumor necrosis: Present.
Macroscopic extent of tumor: Tumor limited to kidney.
Microscopic tumor extension: Tumor limited to kidney.
Surgical margins: Negative.
Lymph-vascular invasion: Not identified.
Lymph nodes: N/A.
Pathologic findings in nonneoplastic kidney: N/A.
Pathologic staging (AJCC 2010): pT2a.
Biorepository sample: Mirror image section of tissue sent for biobanking is positive for involvement by papillary renal cell carcinoma (95%). A separate smaller piece of nonneoplastic kidney is negative for involvement by tumor.
Block(s) containing malignancy suitable for additional testing:
Blocks B3, B4, B8, and B9.

[page 3 of 3]
CLINICAL INFORMATION:

Right renal mass.

SPECIMEN(S):

A: Right kidney lower pole cyst

B: Upper pole right renal mass

GROSS DESCRIPTION:

Performed by Pathologist's Assistant

A. Received fresh labeled and "right kidney lower pole cyst" is an irregular portion of fibromembranous and fatty tissue with no discrete solid area. The specimen is 4 x 2 x 0.8 cm. Entirely submitted in three cassettes labeled A1-A3.

B. Received fresh labeled and "right upper pole renal mass" is a roughly spherical mass of gray-brown tissue covered on surface by soft, lobulated fat. The opposite surface has grossly evident renal parenchyma. The specimen is 803 g and 10 x 9 x 8.5 cm. The grossly evident renal parenchymal margin is inked black. The cut surface demonstrates a dominant central cavity filled with thick, red-brown fluid and necrotic debris. The wall of the structure ranges from 0.3 cm to 1.5 cm in thickness. The thicker areas have associated solid, mottled yellow and tan areas. The inked parenchymal surgical margin ranges from 0.2 cm to 1.5 cm from the mass. There is no gross extension of the mass through the renal capsule. Adrenal gland is not identified. Sampled in ten cassettes labeled B1-B10. B1-B2) Parenchymal surgical margin samples; B3-B9) additional samples of mass; B10) mirror image of biorepository samples (normal kidney and apparent tumor),

Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were developed and whose performance characteristics were determined by

. They have not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ('CLIA') as qualified to perform high complexity clinical laboratory testing.

For Malignancy History		///

Source: NCI Genomic Data Commons file 6476c03f-e84a-4eea-88e5-e2c6d0c883e0 (TCGA-SX-A7SR.59A01820-8FDA-4182-A7C3-708F576DBF1D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).